Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A6B2, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A6B2-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

T2 UCB.

Specimens Submitted:

- 1: Bladder, prostate, seminal vesicles, peri-vesicle lymph nodes, radical cystoprostatectomy
- 2: Right distal pelvic lymph nodes, resection
- 3: Left distal pelvic lymph nodes, resection
- 4: Right distal ureter, excision
- 5: Left distal ureter, excision

ICD-O-3
Carcinoma, urothelial NOS
Site Bladder, posterior wall
path Bladder, NOS
8/20/13
C67.4
C67.9
JW 6/18/13

DIAGNOSIS:

1. Bladder, prostate, seminal vesicles, peri-vesicle lymph nodes, radical cystoprostatectomy:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Flat (in situ carcinoma)

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Right ureter involved

Left ureter involved

Urethra involved

Periurethral prostatic ducts involved

Prostatic stroma involved

Vascular Invasion:

Identified

extensive

Perineural Invasion:

Identified

Surgical Margins:

Tumor present at right ureteral margin

Tumor present at left ureteral margin

Tumor present at urethral margin

For actual ureteral margins, please see parts 4 and 5

Non-Neoplastic Mucosa:

Exhibiting ulceration

Prostate:

Other Extensively involved by urothelial carcinoma

Seminal Vesicles:

Other Involved by invasive urothelial carcinoma, bilateral

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

PR2 (Periprostic or periseminal vesicle soft tissue invasion)

2. Right distal pelvic lymph nodes, resection:

Lymph Node Dissection:

Metastatic urothelial carcinoma

Number of lymph nodes examined: 2

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 1.8cm.

Size of the largest metastatic focus : 0.9 cm.

Extranodal extension is identified

3. Left distal pelvic lymph nodes, resection:

Lymph Node Dissection:

Benign fibroadipose tissue

4. Right distal ureter:

- Urothelial carcinoma in situ

- Resection margin involved by carcinoma in situ

5. Left distal ureter:

- Urothelial carcinoma in situ

- Resection margin involved by carcinoma in situ

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh labeled, "Bladder, prostate, seminal vesicles, peri-vesicle lymph node". It consists of a bladder with attached prostate and adnexa measuring 19.0 cm from superior to inferior, 11.0 cm laterally and 5.0 cm from anterior to posterior. The anterior aspect of the bladder is inked blue and the posterior black. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal hemorrhagic, ulcerated, indurated, necrotic tumor measuring 5.0 x 4.8 x 1.8 cm which is grossly situated within the left and right posterior walls. The tumor grossly involves both the left and right ureteral orifices. Both ureters are probed patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal white-pink cut surface with invades the underlying fat. Possible extension to the inked fat is grossly identified. The remaining bladder mucosa is pink-tan with the normal folds. Two ovoid lesions measuring 0.6 x 0.4 cm are identified at the dome and right posterior wall. Discrete perivesical lymph nodes are grossly not identified. The prostate is serially sectioned to reveal white-tan prostatic parenchyma with multiple yellow foci and white fluid filled cysts identified. A gold thread-like material is identified within the prostate. Representative sections are submitted sections from each prostatic quadrant and transition zone. TPS is submitted, gross photograph taken.

Summary of sections:

UTHM - urethral margin

RUM - right ureter margin

LUM - left ureter margin

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

T - tumor
DL-dome lesion
WL--wall lesion
RUO - right ureter orifice
LUO - left ureter orifice
LP - left posterior wall
LA - left anterior wall
RP - right posterior wall
RA - right anterior wall
TRI -- trigone
DOM - dome
F - perivesical fat
RSV - right seminal vesicle
LSV - left seminal vesicle
RAP - right apex prostate
LAP - left apex prostate
RAM - right anterior mid prostate
RPM - right posterior mid prostate
LAM - left anterior mid prostate
LPM - left posterior mid prostate
RAB - right anterior base prostate
RPB - right posterior base prostate
LAB - left anterior base prostate
LPB - left posterior base prostate

2). The specimen is received in formalin, labeled "Right distal pelvic lymph nodes" and consists of three pink tan firm , fatty lymph nodes ranging from 1.5 to 3.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph node
BL1 - bisected lymph node #1
BL2 - bisected lymph node #2

3). The specimen is received in formalin, labeled "Left distal pelvic lymph nodes" and consists of a portion of yellow tan adipose tissue measuring 4 x 1 x 1 cm. No palpable lymph node is identified. Entirely submitted.

Summary of sections:

U - undesignated

4) The specimen is received in formalin, labeled "right distal ureter- unclipped end is margin" and consists of a gray-tan segment of ureter measuring 0.7 cm in length and 0.4 cm in diameter. A clip is present at one end which is inked black. The opposite end, identified as the margin, is inked blue. The specimen is serially sectioned and totally submitted.

Summary of sections:

M - margin (blue ink)
SS - serial sections

5) The specimen is received in formalin, labeled "left distal ureter- unclipped end is margin" and consists of a gray-tan segment of ureter measuring 2.3 cm in length and 0.4 cm in diameter. A clip is present at one end which is inked black. The opposite end, identified as the margin, is inked blue. The specimen is serially sectioned and totally submitted.

Summary of sections:

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

M - margin (blue ink)
SS - serial sections

Summary of Sections:**Part 1: Bladder, prostate, seminal vesicles, peri-vesicle lymph nodes, radical cystoprostatectomy**

Block	Sect. Site	PCs
1	DL	2
1	DOM	2
1	F	1
1	LA	2
1	LAB	1
1	LAM	1
1	LAP	1
1	LP	2
1	LPB	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
1	RA	2
1	RAB	1
1	RAM	1
1	RAP	1
1	RP	2
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1
1	RUO	1
7	T	7
1	TRI	2
1	UTHM	1
1	WL	2

Part 2: Right distal pelvic lymph nodes, resection

Block	Sect. Site	PCs
2	BL1	2
2	BL2	2
1	LN	1

Part 3: Left distal pelvic lymph nodes, resection

Block	Sect. Site	PCs
3	U	3

Part 4: Right distal ureter, excision

Block	Sect. Site	PCs
1	M	1
1	SS	2

Part 5: Left distal ureter, excision

Block	Sect. Site	PCs
1	M	1

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

2

SS

4

Criteria:	hw 5/5/13	Yes	No
HPA Discrepancy			☒

Source: NCI Genomic Data Commons file 4650d1b2-528a-484e-a659-6d71cb191fac (TCGA-DK-A6B2.B8914E0E-6446-4467-9BB3-08593BFBEFCD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).